Somatic mutation profile of tumor specimen TCGA-CE-A481-01A (aliquot TCGA-CE-A481-01A-21D-A23U-08) from TCGA case TCGA-CE-A481, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.8 years (15,268 days).
Specimen TCGA-CE-A481-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd10afcf-8fee-4cb8-97c4-68678a7f8712.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CE-A481-10A (Blood Derived Normal), aliquot TCGA-CE-A481-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73296caf-68fd-48b7-9310-6c50e82c6a11

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCHE | c.677G>C p.S226T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100013035; called by muse, mutect2, varscan2
- ESS2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as rs755430853, COSV99324125; called by muse, varscan2
- FRMPD1 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1263249674, COSV100899652; called by muse, mutect2, varscan2
- MED12L | c.5479C>A p.L1827I | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs967680584, COSV99854903; called by muse, mutect2, varscan2
- OR6C75 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1314122761, COSV100595465; called by muse, mutect2, varscan2
- PKHD1 | c.8549C>A p.T2850K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100584728; called by muse, mutect2, varscan2
- SUOX | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs546138860, COSV99907233; called by muse, mutect2, varscan2
- USP6 | c.4210_4211del p.M1404Vfs*23 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- MED12L | c.5478C>T p.F1826= | Silent (SNP) | VAF 33/182 reads (18%) | catalogued as rs1020943289, COSV56374735; called by muse, mutect2, varscan2
